TARGET case TARGET-30-PAPDNP — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Retroperitoneum and peritoneum. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/8330ec99-28e7-5ec1-b2da-4cfedaca9678

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Vital status: Dead.

Diagnoses (1)
1. Ganglioneuroblastoma: ICD-O-3 morphology code: 9490/3; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 4.0 years (1,466 days); Year of diagnosis: 2005; Days to last follow up: 235 days; INSS stage: Stage 4.
